Surgical pathology report (de-identified scan), TCGA case TCGA-HE-7128, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HE-7128-01A (Primary Tumor).

[page 1 of 3]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details						
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Site of Primary (Event)	Year of Sample Collection	Age at Sample Collection (yrs)
[REDACTED]	BUFFY	FF		RENL	[REDACTED]	[REDACTED]
	TUMOUR	FF	Left Kidney	RENL		

[page 2 of 3]
Histology and staging							
Sample	Days to	Days to	Type of	Site of Primary	Tumour	Histology	Grade/ Differentiat ion
Comments	Procedure	Diagnosis	Procedure	(Histology)	Size (cm)		
	Date						
			RESECT	L. Kidney	4	Papillary renal car. Type II	X
			RESECT	L. Kidney	4	Papillary renal car. Type II	X

[page 3 of 3]
Pathologic al T	Pathologic al N	Clinical M	Histology Comments	Slide URL
--------------------	--------------------	------------	-----------------------	-----------

T1,NOS	NX	MX		
--------	----	----	--	--

T1,NOS	NX	MX		
--------	----	----	--	--

Source: NCI Genomic Data Commons file c1e924bf-bf54-4e5f-9879-fc7bc3fcb767 (TCGA-HE-7128.DC6C3644-7090-48E4-A6AD-202A029543A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).